Somatic mutation profile of tumor specimen 0DCER1 from CCDI case PBBLSH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,227 days).
Specimen 0DCER1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2f3358b-383b-49a4-8cdf-2d1a38e82493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edb53428-67c9-4657-98b9-751c74b8dd89

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPACA6 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 276/453 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIP2C | c.195T>A p.P65= | Silent (SNP) | VAF 64/462 reads (14%) | called by muse, mutect2, varscan2
- GNAI1 | c.627G>A p.K209= | Silent (SNP) | VAF 28/1185 reads (2%) | called by muse, mutect2
- CKAP2 | c.1479+45C>T | Intron (SNP) | VAF 59/276 reads (21%) | called by muse, mutect2, varscan2
- UGT2A3 | c.*54C>T | 3'UTR (SNP) | VAF 60/272 reads (22%) | catalogued as rs1394108356; called by muse, mutect2, varscan2
